CCDI case PBBMEG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/df51bc0c-30cf-4902-8bf8-02b87185df9e

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 1.8 years (646 days).

Biospecimens (3 samples)
- Sample 0DCBIQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCBIV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCBJ2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
